Gene-level copy-number profile of tumor specimen TCGA-CV-6948-01A from TCGA case TCGA-CV-6948, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 79.8 years (29,153 days).
Specimen TCGA-CV-6948-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.c05db2fa-f329-47d2-bb9c-b542b65e3c6b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6948-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/34ebcefa-6f6e-44c4-8b75-e5357d2c9a21

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 18,817; copy number 2: 35,293; copy number 3: 4,170; copy number 4: 1,390; copy number 5: 62; copy number 6: 8; copy number 7: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6948-01A-11D-1910-01): tumor purity 0.84, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:55,166,910–55,189,214, 2 genes: AC092059.1, LINC02017.
- chr3:86,258,936–86,496,996, 3 genes: AC108733.1, RN7SKP284, LINC02070.
- chr5:96,079,138–96,079,212, 1 gene: MIR583.
- chr9:21,453,802–22,214,672, 23 genes: MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:137,838,419–138,203,325, 8 genes: MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1.
- chr11:16,974,693–16,975,013, 1 gene: AC116533.1.
- chr11:20,670,425–20,671,297, 1 gene: AC090707.1.
- chr12:120,904,702–120,915,123, 2 genes: AC069214.1, CLIC1P1.
- chr16:89,267,630–89,490,561, 1 gene (within-gene range 0–1): ANKRD11.
- chr16:89,420,075–89,459,437, 4 genes: AC092120.1, AC092120.3, RNU6-430P, AC092120.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 82 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:134,257,035–134,689,399, 12 genes, copy number 7 (within-gene range 3–7): RNA5SP218, Y_RNA, AL355881.1, KRT8P42, LINC01010, Z84486.1, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1.
- chr7:38,239,580–38,378,804, 23 genes, copy number 5 (within-gene range 2–5): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2.
- chr14:22,185,562–22,490,553, 39 genes, copy number 5: TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.
- chr19:57,065,334–57,177,921, 8 genes, copy number 6: RPL7AP69, AC025588.4, USP29, ZIM3, AC025588.2, AC025588.3, DUXA, AC025588.1.

Autosomal genes at a single copy (total copy number 1): 16,400. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
